Surgical pathology report (de-identified scan), TCGA case TCGA-AG-3901, project TCGA-READ (Rectum Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AG-3901-01A (Primary Tumor).

Diagnosis:

Rectosigmoidal resection material with inclusion of a moderately differentiated, mucinous adenocarcinoma of the colorectal type, 1.8 cm from the aboral resection margin with a maximum diameter of 4 cm, with circumscribed infiltration of the perirectal fatty tissue and two regional lymph node metastases. Tumor-free colon resection margins. Minimum distance of the tumor from the circumferential resection margin on histological section is 1 cm. Tumor-free mesenteric resection margin.

Tumor stage: pT3, pN1 (2/20) pMX, G2, L1, V0, locally R0

Source: NCI Genomic Data Commons file 8c7ea700-68e4-44b8-b696-9cef8f7100b1 (TCGA-AG-3901.C74EA27C-9F45-4566-BE3D-186750B83817.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).